Gene-level copy-number profile of tumor specimen TCGA-DD-AACL-01A from TCGA case TCGA-DD-AACL, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 66.7 years (24,355 days).
Specimen TCGA-DD-AACL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.41966db3-00ec-4edd-b610-818d6fff241c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AACL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ce2031c6-5bed-4f7d-b008-15544d682191

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10,177; copy number 2: 44,713; copy number 3: 4,819; copy number 4: 102; copy number 5: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AACL-01A-11D-A40Q-01): tumor purity 0.47, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:14,583,084–14,778,560, 8 genes, copy number 5 (within-gene range 3–5): CLEC17A, RN7SL337P, RN7SL842P, ADGRE3, ITGB1P1, AC022149.1, ZNF333, ADGRE2.

Autosomal genes at a single copy (total copy number 1): 10,177. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
